TCGA case TCGA-CD-8528 — Stomach Adenocarcinoma (TCGA-STAD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Stomach; Tissue source site: ILSBio. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/1a1f2197-e303-46e4-8871-53f2eb2e599a

Demographics
Sex at birth: female; Race: asian; Ethnicity: not hispanic or latino; Country of residence at enrollment: Vietnam; Age at index: 43 years; Vital status: Alive.

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; ICD-10 code: C16.3; Tissue or organ of origin: Gastric antrum; Site of resection or biopsy: Stomach, NOS; Classification of tumor: primary; Age at diagnosis: 43.8 years (15,986 days); Year of diagnosis: 2010; AJCC staging edition: 6th; AJCC pathologic T: T4; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIIA; Tumor grade: G3; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Days to last follow up: 375 days (1.0 years).
   Pathology details: Consistent pathology review: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cisplatin + Epirubicin; Days to treatment start: 105 days; Days to treatment end: 232 days; Treatment outcome: Complete Response.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Fluorouracil; Days to treatment start: 105 days; Days to treatment end: 231 days; Treatment outcome: Complete Response.
   Treatment given: Treatment type: Radiation, External Beam; Days to treatment start: 115 days; Days to treatment end: 147 days; Treatment dose: 50 Gy; Treatment outcome: Complete Response; Number of fractions: 25; Treatment anatomic sites: Regional Site.

Follow-up (2 entries)
- Days to follow up: 3 days; Disease response: Tumor Free.
- Days to follow up: 375 days (1.0 years); Disease response: Tumor Free.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-CD-8528-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 1.4; Intermediate dimension: 0.8; Shortest dimension: 0.5.
  Slide TCGA-CD-8528-01A-01-TS1: Section location: Top; Percent tumor cells: 90; Percent tumor nuclei: 85; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 10.
  Slide TCGA-CD-8528-01A-01-BS1: Section location: Bottom; Percent tumor cells: 95; Percent tumor nuclei: 90; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 5.
- Sample TCGA-CD-8528-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-CD-8528-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Stomach, Adenocarcinoma, Not Otherwise Specified (NOS); History neoadjuvant treatment: No; Prospective collection: Yes; Retrospective collection: No; Tumor status: Tumor free; Anatomic organ subdivision: Antrum/Distal; Lymph nodes examined: No; History reflux disease indicator: No; Treatment outcome first course: Complete Remission/Response; New tumor event diagnosis indicator: No.
- Drug treatment 3: Pharmaceutical therapy drug name: 5-Flourouracil.
- Follow-up form: Lost to follow-up: No; New tumor event diagnosis indicator: No; Tumor status: Tumor free; Treatment outcome first course: Complete Remission/Response; Treatment outcome at TCGA followup: Complete Remission/Response.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 375 days; disease-specific survival: no event (censored), 375 days; disease-free interval: no event (censored), 375 days; progression-free interval: no event (censored), 375 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-CD-8528-01A-11D-2338-01): tumor purity 0.55, ploidy 3.17, whole-genome doublings 1.
